CMI case ASCProject_0047 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/529bac26-713c-478c-b516-eca3d91a89f8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 68.3 years (24,959 days).

Biospecimens (2 samples)
- Sample ASCProject_0047_BLOOD_BC: Sample type: DNA; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood.
- Sample ASCProject_0047_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
